Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-7330, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-7330-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: LYMPH NODES, RIGHT PELVIC, EXCISION -

NO EVIDENCE OF NEOPLASIA IN SIX LYMPH NODES (0/6).

PART 2: LYMPH NODES, LEFT PELVIC, EXCISION -

NO EVIDENCE OF NEOPLASIA IN TWELVE LYMPH NODES (0/12).

PART 3: PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY -

- B. PROSTATE ADENOCARCINOMA, GLEASON SCORE $4 + 3 = 7$, WITH A TERTIARY COMPONENT OF GLEASON GRADE 5.
- C. TUMOR FOCALLY SHOWS FEATURES OF DUCTAL ADENOCARCINOMA.
- D. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 1.7 CM IN ONE HISTOLOGIC SECTION.
- E. THE CARCINOMA INVOLVES 28% OF THE EXAMINED PROSTATE VOLUME.
- F. THE CARCINOMA SHOWS ESTABLISHED EXTRACAPSULAR EXTENSION. THE EXTRACAPSULAR EXTENSION IS SEEN IN THE REGION OF THE LEFT ANTERIOR APEX (SLIDES 3S, 3T) AND LEFT POSTERIOR BASE (SLIDES 3II, 3JJ).
- G. BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA.
- H. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- I. PERINEURAL INVASION IS IDENTIFIED.
- J. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- K. HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- L. PATHOLOGIC TNM STAGE: pT3a N0 MX.
- M. BACKGROUND PROSTATE TISSUE WITH NODULAR HYPERPLASIA AND CHRONIC INFLAMMATION.

PART 4: LEFT NEUROVASCULAR BUNDLE, EXCISION -

- A. FIBROVASCULAR AND ADIPOSE TISSUE AND NERVE BUNDLES AND GANGLION CELLS.
- B. NO EVIDENCE OF CARCINOMA SEEN.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA:	PSA value: 6.2
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
	Other Type(s): Focal areas with ductal features
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	3
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	60%
WEIGHT OF PROSTATE:	82.49gm
TUMOR SIZE:	Maximum dimension: 3.3 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	> 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	Yes - Established (> 0.8mm)
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	18
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT3a
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file b9ff3793-9482-458a-aa66-3b1345a93eed (TCGA-EJ-7330.D910CD86-89BE-4FC9-8F9D-497692A6FACE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).